Somatic mutation profile of tumor specimen TCGA-LN-A49U-01A (aliquot TCGA-LN-A49U-01A-31D-A27G-09) from TCGA case TCGA-LN-A49U, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 62.9 years (22,969 days).
Specimen TCGA-LN-A49U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dddf9ff7-4547-430b-aedd-95d6604e92c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49U-10A (Blood Derived Normal), aliquot TCGA-LN-A49U-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37d60ccc-c9f8-4343-8333-34fb8ea17ef2

The open-access MAF lists 144 somatic variants for this specimen: 101 protein-altering or splice-affecting, 38 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 38, Nonsense Mutation 5, Splice Site 3, 3'Flank 2, RNA 2, Frame Shift Del 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.372C>A p.C124* | Nonsense Mutation (SNP) | VAF 227/291 reads (78%) | catalogued as rs1555526478, CM1210346, COSV52731101, COSV52944837; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACBD5 | c.1271G>A p.R424Q (on ENST00000375888 / NM_001352568.1; = p.R415Q on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.241); catalogued as rs543720340, COSV101022460; called by muse, mutect2, varscan2
- ACSS2 | c.1061G>C p.W354S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53627787; called by muse, mutect2, varscan2
- ADAM8 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1023195047, COSV69864780; called by muse, mutect2, varscan2
- AMBRA1 | c.1783G>A p.E595K (on ENST00000458649 / NM_001367468.1; = p.E505K on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as rs1208213614, COSV54047898, COSV54062127; called by muse, mutect2, varscan2
- ATXN10 | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1287906200; called by muse, mutect2, varscan2
- BCS1L | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs372817977; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP3 | c.405C>G p.F135L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV66518014, COSV66518629; called by muse, mutect2, varscan2
- CCZ1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.406); catalogued as rs1485386193; called by muse, mutect2, varscan2
- CDC123 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1199885801, COSV55399388; called by muse, mutect2, varscan2
- CNPPD1 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV55409991; called by muse, mutect2, varscan2
- DNASE1L1 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV50011456; called by muse, mutect2, varscan2
- EIF2B1 | c.102G>C p.L34F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV57459800; called by muse, mutect2, varscan2
- GPBP1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV53314224; called by muse, mutect2, varscan2
- GRIN2D | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs768177826, COSV53520309; called by muse, mutect2, varscan2
- KIF26A | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 102/132 reads (77%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs1332936946; called by muse, mutect2, varscan2
- KRTAP9-9 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 112/218 reads (51%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.929); catalogued as rs771073194; called by muse, mutect2, varscan2
- LPO | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763760771; called by muse, mutect2, varscan2
- MED1 | c.4424C>T p.S1475F | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1264023379; called by muse, mutect2, varscan2
- METTL15 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs967867843; called by muse, mutect2, varscan2
- MMS22L | c.3159G>C p.L1053F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV51517241, COSV99247690; called by muse, mutect2, varscan2
- MYH14 | c.3935C>T p.A1312V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs561525083; called by muse, mutect2, varscan2
- NBPF9 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1553656178; called by muse, varscan2
- NLRP4 | c.2644C>A p.Q882K | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56708718; called by muse, mutect2, varscan2
- OR2G6 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs868064086; called by muse, mutect2, varscan2
- PABPC1 | c.740C>A p.A247D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59401462; called by muse, mutect2, varscan2
- PAK4 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780200774; called by muse, mutect2, varscan2
- PSMC4 | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV50097985; called by muse, mutect2, varscan2
- RHPN1 | c.1781C>G p.S594C | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV56649993; called by muse, mutect2, varscan2
- RINT1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs923333938; called by muse, mutect2, varscan2
- SCUBE3 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752868196, COSV99234369; called by muse, mutect2, varscan2
- SEMA5A | c.3212A>T p.Y1071F | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.577); catalogued as rs890858469; called by muse, mutect2, varscan2
- SIPA1L2 | c.3416G>A p.R1139K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV53385903; called by muse, mutect2, varscan2
- SNX13 | c.434C>G p.A145G | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV68066726; called by muse, mutect2, varscan2
- SRCAP | c.3952C>T p.R1318W | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs753316154; called by muse, mutect2, varscan2
- SWT1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as rs1364296965, COSV62253356; called by muse, mutect2, varscan2
- TADA2B | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV53828283; called by muse, varscan2
- TMEM132D | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV70621341; called by muse, mutect2, varscan2
- TOX3 | c.1641C>G p.I547M | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV54863143, COSV54872161; called by muse, mutect2, varscan2
- TUBA3C | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV68029500; called by muse, mutect2, varscan2
- XKR7 | c.1060A>C p.K354Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1241364768; called by muse, mutect2, varscan2
- ZBED4 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53464574; called by muse, mutect2, varscan2
- ZNF672 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs371348856, COSV60637620; called by muse, varscan2
- ACSS2 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK3 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKS3 | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP36 | c.1600C>G p.R534G | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); called by muse, varscan2
- CARS1 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCNY | c.265-1G>A p.X89_splice | Splice Site (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- CCT6A | c.661A>T p.M221L | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- CENPF | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- CORO2A | c.922A>T p.S308C | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CSMD3 | c.8258A>G p.Y2753C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CTDP1 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- CUL7 | c.4826G>A p.S1609N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CYTH3 | c.456C>G p.F152L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- DIS3 | c.1594C>T p.L532F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIS3L | c.1622C>G p.S541C (on ENST00000319212 / NM_001143688.3; = p.S458C on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- DNASE1L1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF4G2 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EPB41L5 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- EPHA4 | c.128T>A p.L43H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR149 | c.530G>C p.R177P | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GPR52 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGSF9B | c.1765G>T p.G589* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- IQCB1 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KMT2D | c.6005G>T p.S2002I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LUC7L | c.1024A>T p.S342C | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MMS22L | c.3386T>A p.V1129D | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTIF2 | c.1565-2A>G p.X522_splice | Splice Site (SNP) | VAF 12/24 reads (50%) | called by muse, varscan2
- MUC4 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- NEDD8 | c.146A>G p.Q49R | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NEU4 | c.208G>T p.A70S (on ENST00000391969 / NM_001167602.3; = p.A82S on NM_080741.4) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NOC3L | c.1723A>G p.I575V | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.347); called by muse, mutect2
- NUDT8 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ODR4 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OSBPL3 | c.734_737dup p.H247Pfs*19 | Frame Shift Ins (INS) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- PAXIP1 | c.2742C>G p.F914L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PCDHB2 | c.2153G>C p.R718T | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PHYHIPL | c.204_205del p.S69Mfs*17 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.4483A>T p.I1495F | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMB10 | c.681_685del p.S229Tfs*46 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- RASA1 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- RCOR3 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- RELN | c.7789G>A p.E2597K | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RHPN1 | c.1877C>G p.S626C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC31A | c.1997C>T p.S666L (on ENST00000355196 / NM_001318120.1; = p.S627L on NM_016211.4) | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- SELENOI | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- SLA2 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, varscan2
- SLAMF6 | c.382+1G>C p.X128_splice | Splice Site (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- SNX13 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SP3 | c.2267C>G p.T756S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPDYC | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM132D | c.332T>G p.M111R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- TUBB2A | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- UBAP2 | c.2894C>G p.T965R | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- UBE2M | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF292 | c.4184C>G p.S1395C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF451 | c.2902C>T p.Q968* (on ENST00000370706 / NM_001031623.3; = p.Q920* on NM_015555.2) | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- ZNF671 | c.841G>T p.G281* | Nonsense Mutation (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- ZNF81 | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACTN2 | c.1725C>A p.I575= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV100856606; called by muse, mutect2, varscan2
- AKAP13 | c.6060C>T p.Y2020= (on ENST00000394518 / NM_007200.5; = p.Y2024= on NM_006738.6) | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs1388110117; called by muse, mutect2, varscan2
- ANKRD30A | c.2631A>C p.P877= (on ENST00000611781; = p.P821= on NM_052997.2) | Silent (SNP) | VAF 73/177 reads (41%) | called by muse, mutect2, varscan2
- BCDIN3D | c.141C>A p.L47= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV61702840; called by muse, mutect2, varscan2
- CALCB | c.123C>T p.L41= | Silent (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.4176A>G p.K1392= (on ENST00000236925 / NM_001297707.2; = p.K1381= on NM_203459.3) | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV52671193; called by muse, mutect2, varscan2
- CDK11A | c.2040C>G p.L680= (on ENST00000378633 / NM_001313896.2; = p.L677= on NM_024011.4) | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as rs1485816575; called by muse, mutect2, varscan2
- CHAMP1 | c.1533C>T p.A511= | Silent (SNP) | VAF 31/49 reads (63%) | called by muse, mutect2, varscan2
- CHRNB3 | c.432C>T p.T144= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99251447; called by muse, mutect2, varscan2
- COPB1 | c.1371A>G p.G457= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs972259116; called by muse, mutect2, varscan2
- COPS6 | c.495C>T p.V165= | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- CRB2 | c.1683G>A p.P561= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs763374681; called by muse, mutect2, varscan2
- CYTH3 | c.600C>G p.L200= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as rs1400785180; called by muse, mutect2, varscan2
- ENAM | c.1497A>T p.G499= | Silent (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- FLT1 | c.2496A>C p.S832= | Silent (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- FOXH1 | c.69G>A p.R23= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs895247507; ClinVar: likely benign; called by muse, mutect2, varscan2
- GJC2 | c.843C>T p.L281= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1282557468, COSV100812989; called by muse, mutect2, varscan2
- HSPA1B | c.1767G>A p.K589= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs1256471496; called by muse, mutect2, varscan2
- KIF17 | c.297C>T p.F99= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV56119796; called by muse, mutect2
- MYH11 | c.1140A>G p.K380= | Silent (SNP) | VAF 48/129 reads (37%) | called by muse, mutect2, varscan2
- NR4A2 | c.216C>T p.D72= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs1285833990; called by mutect2, varscan2
- OR4K1 | c.306C>T p.F102= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs772261875, COSV53459148; called by muse, mutect2, varscan2
- OR5T3 | c.669C>A p.I223= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as rs866879324; called by muse, mutect2, varscan2
- PARP14 | c.5337T>C p.H1779= | Silent (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.1272C>T p.G424= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs1282174658; called by muse, mutect2, varscan2
- PKD2 | c.1878C>T p.F626= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- PTPRM | c.2358G>A p.V786= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV100155614; called by muse, mutect2, varscan2
- PYY | c.168C>G p.L56= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV63970373; called by muse, mutect2, varscan2
- SLC12A5 | c.1704C>T p.C568= (on ENST00000454036 / NM_001134771.2; = p.C545= on NM_020708.5) | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs1050069491; called by muse, mutect2, varscan2
- SPATA31E1 | c.2781G>A p.Q927= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, varscan2
- TAOK3 | c.18G>A p.L6= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs779780610; called by muse, mutect2, varscan2
- TENM2 | c.1524C>T p.F508= (on ENST00000518659 / NM_001122679.2; = p.F276= on NM_001080428.3) | Silent (SNP) | VAF 54/97 reads (56%) | called by muse, mutect2, varscan2
- TREM1 | c.93G>A p.L31= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs759126895; called by muse, mutect2, varscan2
- WHRN | c.2469G>A p.A823= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as rs144207463; called by muse, mutect2, varscan2
- ZKSCAN3 | c.678A>G p.E226= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs745896649; called by muse, mutect2, varscan2
- ZMYM1 | c.945G>A p.K315= | Silent (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- ZNF320 | c.153C>T p.S51= | Silent (SNP) | VAF 53/192 reads (28%) | called by muse, mutect2, varscan2
- ZNF99 | c.2145C>T p.S715= | Silent (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- C7orf65 | n.423C>A | RNA (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- EBAG9 | c.522-1018C>T | Intron (SNP) | VAF 99/172 reads (58%) | called by muse, mutect2, varscan2
- ESPN | chr1:6457261 G>C | 3'Flank (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- ESPN | chr1:6460017 G>A | 3'Flank (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- SSPOP | n.10955G>C | RNA (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100947813; called by muse, mutect2, varscan2
